Somatic mutation profile of tumor specimen C3N-02920-03 (aliquot CPT0216290006) from CPTAC case C3N-02920, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 48.9 years (17,859 days).
Specimen C3N-02920-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8c3b83f-a0a8-41ee-80ab-6fa802b297c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02920-71 (Blood Derived Normal), aliquot CPT0216390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcbdbc7d-0c0b-4d5f-a36c-c33c84e0fb5a

The open-access MAF lists 56 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 4, 3'UTR 3, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 63/487 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs372549560, COSV52367664; ClinVar: uncertain significance; called by muse, mutect2
- AHRR | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs201403478; called by muse, mutect2
- ANAPC1 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1178449941; called by muse, mutect2
- ASIC3 | c.535-7G>A | Splice Region (SNP) | VAF 22/360 reads (6%) | catalogued as rs752414495; called by muse, mutect2
- CFAP74 | c.2930C>T p.T977M | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.488); catalogued as rs761689024; called by muse, mutect2, varscan2
- EIF3E | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV55204316; called by muse, mutect2
- FFAR1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199506594, COSV50050607; called by muse, mutect2, varscan2
- HLCS | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103228, CM960836, COSV60795798; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- KEL | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62333627; called by muse, mutect2
- LMTK3 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54313459; called by muse, mutect2
- MRPS10 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766459845; called by muse, mutect2
- NKIRAS2 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100288832; called by muse, mutect2, varscan2
- OR1L1 | c.299G>A p.R100H (on ENST00000373686; = p.R50H on NM_001005236.3) | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs148839355; called by muse, mutect2, varscan2
- SALL3 | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV73306707; called by muse, mutect2
- SUGP2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs372273190; called by muse, mutect2
- ZNF208 | c.1575C>A p.Y525* | Nonsense Mutation (SNP) | VAF 20/402 reads (5%) | catalogued as rs911022859; called by muse, mutect2
- AC242842.3 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 12/534 reads (2%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS15 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- CAT | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2
- DNAH14 | c.10193T>A p.I3398N (on ENST00000445597; = p.I4406N on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DNAH6 | c.8452C>T p.L2818F | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPC6 | c.822G>C p.M274I | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- GRM6 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- IRS2 | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MTHFD1L | c.2512T>A p.S838T | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- NQO1 | c.172+2T>C p.X58_splice | Splice Site (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- OTOA | c.2082C>G p.Y694* (on ENST00000286149; = p.Y680* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- SENP1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC40A1 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- SYNE1 | c.1235G>A p.G412D (on ENST00000367255 / NM_182961.4; = p.G419D on NM_033071.3) | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TNXB | c.6258G>C p.R2086S (on ENST00000647633; = p.R1839S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- AXIN1 | c.1041G>A p.R347= | Silent (SNP) | VAF 30/542 reads (6%) | called by muse, mutect2
- CACNA1E | c.6489G>A p.P2163= (on ENST00000367573 / NM_001205293.3; = p.P2120= on NM_000721.4) | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as rs377180948, COSV62388209; called by muse, mutect2, varscan2
- CNOT4 | c.1743C>G p.S581= (on ENST00000541284 / NM_001190850.1; = p.S578= on NM_001190849.2) | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- CYLC2 | c.783G>A p.K261= | Silent (SNP) | VAF 15/181 reads (8%) | catalogued as COSV66336937; called by muse, mutect2
- DISP1 | c.834G>A p.E278= | Silent (SNP) | VAF 10/259 reads (4%) | called by muse, mutect2
- ERAP2 | c.2199G>A p.V733= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- FILIP1L | c.3294G>T p.G1098= (on ENST00000354552 / NM_182909.3; = p.G858= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- MBD6 | c.972C>T p.L324= | Silent (SNP) | VAF 13/266 reads (5%) | catalogued as rs1187803586; called by muse, mutect2
- NUP155 | c.2484C>T p.I828= (on ENST00000231498 / NM_153485.3; = p.I769= on NM_004298.4) | Silent (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- RD3 | c.102G>A p.T34= | Silent (SNP) | VAF 26/496 reads (5%) | catalogued as rs199511076, COSV65362498, COSV65363068; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- SETBP1 | c.3594G>A p.P1198= | Silent (SNP) | VAF 34/390 reads (9%) | catalogued as rs200032059; called by muse, mutect2
- SLC35D3 | c.618C>T p.F206= | Silent (SNP) | VAF 11/226 reads (5%) | called by muse, mutect2
- SUPT20HL2 | c.1578C>T p.A526= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as rs1021517794; called by muse, mutect2, varscan2
- ZNF679 | c.540A>T p.G180= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- ATP6V0B | c.591+61C>G | Intron (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- CADM1 | chr11:115504427 C>T | 5'Flank (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- CCDC191 | c.-12C>A | 5'UTR (SNP) | VAF 20/421 reads (5%) | called by muse, mutect2
- CD8A | c.*515G>A | 3'UTR (SNP) | VAF 18/219 reads (8%) | catalogued as rs1009448994; called by muse, mutect2
- GEMIN2 | c.406-496C>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- NCOA4 | c.*14A>G | 3'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- NSD3 | c.1855+919A>G | Intron (SNP) | VAF 10/294 reads (3%) | called by muse, mutect2
- REG4 | c.165+147T>C | Intron (SNP) | VAF 13/171 reads (8%) | catalogued as rs912009219; called by muse, mutect2
- XIAP | c.*6709G>T | 3'UTR (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
